CMI case ASCProject_0007 — CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/ba243c01-9dc9-4209-b9e4-7f6b136b8d71

Demographics
Sex at birth: male.

Diagnoses (1)
1. Angiosarcoma: Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Age at diagnosis: 41.9 years (15,314 days).

Biospecimens (3 samples)
- Sample ASCProject_0007_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Samples ASCProject_0007_T1_RNA, ASCProject_0007_T1_WES (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Bladder; Preservation method: FFPE.
